Gene-level copy-number profile of specimen HCM-CSHL-0878-C18-85A from HCMI case HCM-CSHL-0878-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.1 years (19,396 days).
Specimen HCM-CSHL-0878-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb06612f-b10c-4c9d-90d5-410ac3d7b523.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0878-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/e92a25bb-b837-4431-8bf1-1f5784ec6cfc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 460; copy number 1: 13,659; copy number 2: 43,626; copy number 3: 756; copy number 4: 125; copy number 5: 59; copy number 6: 9; copy number 7: 18; copy number 8: 36; copy number 9: 9; copy number 10: 29; copy number 11: 42; copy number 12: 28; copy number 13: 4; copy number 14: 5; copy number 16: 20; copy number 20: 18; copy number 22: 8.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–1,708,476, 26 genes (within-gene range 0–2): AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 285 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,327,399–119,356,182, 1 gene, copy number 9 (within-gene range 2–9): LINC01780.
- chr1:119,368,779–119,394,130, 2 genes, copy number 9: HAO2, HAO2-IT1.
- chr8:37,326,575–37,849,861, 18 genes, copy number 7: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2.
- chr13:26,755,200–30,429,758, 76 genes, copy number 11–22 (broad region; genes not listed).
- chr20:19,823,443–19,823,943, 1 gene, copy number 5: RPL12P12.
- chr20:24,679,547–30,399,257, 57 genes, copy number 5–11: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A, CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP.
- chr20:31,257,664–32,439,319, 55 genes, copy number 5–6: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1.
- chr20:33,980,679–34,123,290, 6 genes, copy number 10–11: RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1.
- chr20:37,903,111–38,712,103, 35 genes, copy number 8–9: VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP.
- chr20:40,685,848–41,366,818, 15 genes, copy number 8–10: MAFB, AL035665.1, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3.
- chr20:52,972,358–53,668,758, 14 genes, copy number 11–14: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.
- chr20:58,150,902–58,367,507, 4 genes, copy number 5: C20orf85, ANKRD60, PPP4R1L, RAB22A.
- chr20:63,558,086–63,574,239, 1 gene, copy number 12: HELZ2.

Autosomal genes at a single copy (total copy number 1): 13,659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
